Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMY, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMY-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

TCGA-XF-AMY-01A-PR

Collected
Ordered by

Location

**DIAGNOSIS:**

SALVAGE CYSTECTOMY WITH ILEAL-CONDUIT:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- HYDROURETER AND NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- HYDROURETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER (C):

GROSS CONSULTATION DIAGNOSIS:

- TUMOR IDENTIFIED IN PERIVESICAL FAT, MARGIN GROSSLY NEGATIVE FOR MALIGNANCY

FINAL DIAGNOSIS:

- INVASIVE UROTHELIAL CARCINOMA, NUCLEAR GRADE 3/4, ARISING IN THE RIGHT LATERAL WALL INVADING THROUGH THE MUSCULARIS PROPRIA INTO THE PERIVESICAL FAT MEASURING 4 X 4 X 1.8 CM

- SEPARATE FOCUS OF HIGH-GRADE PAPILLARY UROTHELIAL CARCINOMA WITH SUPERFICIAL INVASION INTO THE LAMINA PROPRIA INVOLVING LEFT LATERAL WALL

- MULTIFOCAL UROTHELIAL CARCINOMA IN SITU

- URETHRAL, RADIAL, BILATERAL URETER MARGINS ARE FREE OF MALIGNANCY (TUMOR PRESENT WITHIN 2 MM OF INKED RADIAL MARGIN)

- NON-NEOPLASTIC BLADDER SHOWS INFLAMMATION AND REACTIVE ATYPIA

- FOREIGN BODY GIANT CELL REACTION AND SCAR TISSUE IDENTIFIED CONSISTENT WITH PREVIOUS BIOPSY SITE

RIGHT DISTAL URETER (D):

- HYDROURETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PARARECTAL TISSUE (E):

- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE

- NO MALIGNANCY IDENTIFIED

RIGHT COMMON ILIAC LYMPH NODE (F):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

AORTIC BIFURCATION LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT EXTERNAL ILIAC LYMPH NODE (H):

- BENIGN FIBROADIPOSE TISSUE

- NO MALIGNANCY IDENTIFIED

- NO LYMPH NODES IDENTIFIED (0/0)

LEFT EXTERNAL ILIAC LYMPH NODE (I):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT PROXIMAL URETER (J):

- HYDROURETER

ICD-O-3
Carcinoma, urothelial, papillary
Site: Bladder, NOS. C67.9
Bladder, lateral wall
C67.2
8/30/13
W3/26/14

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (K):

- HYDROURETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY:

NO MALIGNANCY IDENTIFIED IN 13 LYMPH NODES
EXAMINED (0/13)

PATHOLOGIC TNM STAGE:

pT3b NO MX, STAGE III

Electronically signed by

Verified:

SPECIMEN SOURCE:

A: "Right distal ureter"
B: "Left distal ureter"
C: "Bladder"
D: "Right distal ureter"
E: "Right para rectal tissue"
F: "Right common iliac"
G: "Aortic bifurcation"
H: "Rt. external iliac L.N."
I: "Left external iliac L.N."
J: "Right proximal ureter"
K: "Left proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter". It consists of a segment of ureter measuring 0.9 x 0.5 x 0.2 cm. The specimen is submitted entirely in one cassette for frozen section diagnosis.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter". It consists of a segment of ureter measuring 0.7 x 0.5 x 0.2 cm. The specimen is submitted entirely in one cassette for frozen section diagnosis.

C: The specimen is received fresh from the O.R. at the request of the surgeon for an intraoperative consultation and labeled "Bladder". It consists of a cystectomy specimen measuring overall 23 x 10 x 3 cm. The peritoneum measures 16 x 8 by less than 0.1 cm and is smooth, glistening and freely mobile. The bladder measures 8 x 6 x 2 cm with a wall thickness of 1 cm. The non-peritonealized bladder is inked black and the specimen is opened anteriorly along the urethra. There is a large amount of clotted blood occupying the bladder. Located along the right bladder wall surrounding the right ureteral orifice is a firm, tan-pink, infiltrative mass which is located submucosally measuring 4 x 4 cm. There is an exophytic and ulcerative portion of tumor attached to this main mass measuring 2 x 2 x 2 cm. Sectioning through the mass shows a 1.8 cm depth of invasion with a bladder wall thickness of 1.1 cm. The tumor grossly involves the perivesical fat and is located 0.5 cm from the closest inked radial margin. Located slightly above the tumor is a scar measuring 0.8 cm in greatest dimension. There is also a soft tan-pink nodule

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

Location:

along the left lateral wall measuring 0.5 cm. Also identified is a small cavity site along the left ureterovesical junction measuring 0.3 x 0.3 x 0.2 cm. The urethral bladder neck measures approximately 1 cm. The remaining bladder mucosa is soft, tan-pink and slightly edematous. The attached right ureter measures 3.8 cm in length by 1.5 cm in circumference and shows the tumor undermining the mucosal surface. The attached left ureter measures 3.5 cm in length by 1 cm in circumference and is grossly unremarkable. There is no attached prostate. Representative sections are submitted in 18 cassettes.

D: The specimen is received in formalin and labeled "Right distal ureter". It consists of a segment of ureter measuring 3.6 cm in length by 0.6 cm in average diameter. A single black suture is noted at one end and the ureter is grossly dilated along that surface measuring 0.9 cm in greatest diameter. The end opposite the suture is inked black. The specimen is serially sectioned and entirely submitted in two cassettes.

E: The specimen is received in formalin and labeled "Right para rectal tissue". It consists of two pieces of soft to firm, tan-yellow, fibroadipose tissue. The larger one measures 7 x 1.2 x 0.6 cm, and the smaller measuring 2.2 x 0.9 x 0.5 cm. The larger specimen is serially sectioned showing homogenous fat. No mass lesion is identified. The entire specimen is submitted in six cassettes.

F: The specimen is received in formalin and labeled "Right common iliac". It consists of two pieces of soft tan-yellow fibroadipose tissue measuring in aggregate 6 x 3 x 1.1 cm. Two lymph nodes are identified, the largest one measures 2.2 cm in greatest dimension. The specimen is entirely submitted in three cassettes.

G: The specimen is received in formalin and labeled "Aortic bifurcation". It consists of multiple pieces of soft tan-yellow fibroadipose tissue measuring in aggregate 7 x 6 x 2.5 cm. No discrete masses are identified. The specimen is submitted entirely in 13 cassettes.

H: The specimen is received in formalin and labeled "Rt. external iliac L.N.". It consists of multiple pieces of soft tan-yellow fibroadipose tissue measuring in aggregate 4 x 3 x 1.5 cm. No discrete masses are identified. The specimen is entirely submitted in two cassettes.

I: The specimen is received in formalin and labeled "Left external iliac L.N.". It consists of multiple pieces of soft tan-yellow fibroadipose tissue measuring in aggregate 3.5 x 3.1 x 0.8 cm. No discrete masses are identified. The specimen is entirely submitted in two cassettes.

J: The specimen is received in formalin and labeled "Right proximal ureter". It consists of a segment of dilated ureter measuring 1 cm in length by 0.8 cm in diameter. There is a suture noted on one end of the specimen. The end opposite the suture is inked black. The specimen is bisected and entirely submitted in one cassette.

K: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a segment of a ureter measuring 1.5 cm in length by 1 cm in diameter. Multiple metallic clips are present predominantly on one end of the ureter. The end opposite to the clip is inked black. The specimen is serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
C1: urethral margin
C2: right distal ureter

[page 4 of 4]
Collected

Ordered by

Location

C3: left distal ureter
C4: left wall nodule
C5: right wall scar
C6: right wall scar
C7: right ureterovesical junction
C8: left ureterovesical junction with biopsy cavity
C9: trigone with bladder neck
C10: dome
C11: tumor with right ureter
C12-14: tumor section
C15-16: tumor with radial margin, bisected
C17: right perivesical fat
C18: left perivesical fat
D1: right distal ureter; end opposite suture with black ink
D2: suture site, black ink on most distal ureter portion
E1: right pararectal tissue; smaller fragment
E2-6: larger fragment, entirely submitted
F1: right common iliac; largest lymph node, bisected
F2: one lymph node
F3: remaining tissue
G1-13: aortic bifurcation - all embedded
H1,2: right external iliac lymph node - all embedded
I1,2: left external iliac lymph node - all embedded
J: right proximal ureter - all embedded
K: left proximal ureter - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- hydroureter and no tumor identified

BFS: Left distal ureter:
- no tumor identified

INTRAOPERATIVE GROSS CONSULTATION

Bladder (C):
- tumor identified in perivesicle fat
- margin grossly negative for malignancy

MICROSCOPIC EXAMINATION:

A-K: See final microscopic-diagnoses.

Source: NCI Genomic Data Commons file 56d22b58-c946-4fa1-8d70-4c50b997bef7 (TCGA-XF-AAMY.AEF3C925-7B93-42F8-921B-9A2D3912DE99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).